Somatic mutation profile of tumor specimen TARGET-30-PATVDI-01A (aliquot TARGET-30-PATVDI-01A-01D) from TARGET case TARGET-30-PATVDI, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 8.2 years (3,003 days).
Specimen TARGET-30-PATVDI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f9d9c9c9-834c-4406-99e6-bc4dc6bb079a.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PATVDI-10A (Blood Derived Normal), aliquot TARGET-30-PATVDI-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ad4418f6-6d3f-4cb0-910a-9cfd7d2850c9

The open-access MAF lists 6 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Silent 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARFGEF3 | c.848G>T p.S283I | Missense Mutation (SNP) | VAF 31/184 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MYH2 | c.4146G>T p.E1382D | Missense Mutation (SNP) | VAF 26/184 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PTPRA | c.1989G>T p.K663N | Missense Mutation (SNP) | VAF 37/193 reads (19%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- FAT1 | c.4995G>T p.P1665= | Silent (SNP) | VAF 23/230 reads (10%) | catalogued as COSV101499346; called by muse, mutect2
- RYR1 | c.13545C>A p.P4515= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as COSV62089874, COSV62094454; called by muse, mutect2, varscan2
- ALPK2 | c.*132C>T | 3'UTR (SNP) | VAF 44/321 reads (14%) | called by muse, mutect2, varscan2
